Somatic mutation profile of tumor specimen HCM-WCMC-0950-C67-01A (aliquot HCM-WCMC-0950-C67-01A-01D-A88H-36) from HCMI case HCM-WCMC-0950-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma, non-invasive; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 63.0 years (23,007 days).
Specimen HCM-WCMC-0950-C67-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 178aa9f2-e5dd-486a-992f-0781e3a189b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0950-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0950-C67-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84c73b15-52e4-43fc-b693-95c0b1df88c9

The open-access MAF lists 84 somatic variants for this specimen: 65 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 15, Nonsense Mutation 6, Frame Shift Ins 3, Splice Region 2, 3'UTR 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 52/170 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP2 | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV57042260; called by muse, mutect2, varscan2
- ADPRHL1 | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.045); catalogued as rs564314253; called by muse, mutect2, varscan2
- AP1B1 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1472515670; called by muse, mutect2, varscan2
- ARID2 | c.4030A>G p.I1344V | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1483452285; called by muse, mutect2, varscan2
- ASXL1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 44/325 reads (14%) | catalogued as COSV100038917; called by muse, mutect2, varscan2
- C7orf33 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 150/341 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as rs1383277607, COSV61022645; called by muse, mutect2, varscan2
- CSPG4 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1316954384; called by muse, mutect2, varscan2
- ENTPD3 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57193342; called by muse, mutect2, varscan2
- FHDC1 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377374100; called by muse, mutect2, varscan2
- FLG2 | c.1649C>G p.S550* | Nonsense Mutation (SNP) | VAF 147/550 reads (27%) | catalogued as COSV66166296; called by muse, mutect2, varscan2
- FMN2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100142594; called by muse, mutect2, varscan2
- FOXR2 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 208/244 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs976952186; called by muse, mutect2, varscan2
- H3-3A | c.14A>T p.K5M | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); catalogued as COSV64733602; called by muse, mutect2, varscan2
- MBD1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 78/175 reads (45%) | catalogued as COSV53998173; called by muse, mutect2, varscan2
- PDCD11 | c.1188C>G p.L396= | Splice Region (SNP) | VAF 62/130 reads (48%) | catalogued as rs765866265, COSV63934789, COSV63935432; called by muse, mutect2, varscan2
- PMS2 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1461669945, COSV56224444; called by muse, mutect2, varscan2
- SF3B1 | c.2680G>C p.D894H | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59214349, COSV59219610; called by muse, mutect2, varscan2
- SI | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 98/185 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as rs202151060, COSV52281397, COSV52284527; called by muse, mutect2, varscan2
- ZNF324 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.302); catalogued as rs778628205, COSV52179765; called by muse, mutect2, varscan2
- ZNF577 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 144/340 reads (42%) | catalogued as rs1279611523; called by muse, mutect2, varscan2
- ZNF585A | c.2199G>C p.L733F (on ENST00000292841 / NM_001288800.2; = p.L678F on NM_152655.3) | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV53063603; called by muse, mutect2, varscan2
- ANKRD17 | c.5063C>G p.S1688C | Missense Mutation (SNP) | VAF 77/234 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ATP2B2 | c.1157T>A p.I386N (on ENST00000352432; = p.I352N on NM_001683.5) | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHI3L1 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- DIS3L2 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 126/177 reads (71%) | called by muse, mutect2, varscan2
- DMP1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 144/382 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- EXOC6B | c.1446A>G p.Q482= | Splice Region (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- GGT5 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- GREB1L | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- GRM1 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- HCN3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 67/572 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMCN1 | c.11839C>A p.L3947M | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ID1 | c.80dup p.A28Cfs*10 | Frame Shift Ins (INS) | VAF 200/403 reads (50%) | called by mutect2, varscan2
- IL18 | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- IL1RAPL1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- IRX1 | c.196G>C p.A66P | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.184); called by muse, varscan2
- JUNB | c.612dup p.G205Rfs*179 | Frame Shift Ins (INS) | VAF 106/262 reads (40%) | called by mutect2, varscan2
- KIF2C | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 95/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KLHL34 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2
- KRT10 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 221/620 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MEGF10 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 110/231 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MXD4 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NPEPPS | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR12D1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD7A | c.2575A>G p.T859A (on ENST00000307050 / NM_001382637.1; = p.T852A on NM_130901.3) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PAX1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, varscan2
- PCDHGA4 | c.1281G>C p.K427N | Missense Mutation (SNP) | VAF 105/205 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POGZ | c.2407T>G p.L803V | Missense Mutation (SNP) | VAF 189/322 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PRUNE2 | c.6594C>A p.D2198E | Missense Mutation (SNP) | VAF 169/204 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRC | c.2029A>C p.N677H | Missense Mutation (SNP) | VAF 115/410 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RAPGEF4 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 35/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RASGRP3 | c.2020G>A p.E674K (on ENST00000402538 / NM_001349975.2; = p.E673K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/276 reads (46%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RGS9BP | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPP25 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- RSPH6A | c.2065C>G p.L689V | Missense Mutation (SNP) | VAF 131/283 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, varscan2
- SLC26A2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 159/290 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLC5A5 | c.1878G>A p.W626* | Nonsense Mutation (SNP) | VAF 83/190 reads (44%) | called by muse, mutect2, varscan2
- SOAT1 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 201/336 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOBP | c.1962C>G p.I654M | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SP9 | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 229/433 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STAG2 | c.310dup p.E104Gfs*6 | Frame Shift Ins (INS) | VAF 37/45 reads (82%) | called by mutect2, varscan2
- TDRD15 | c.1299C>G p.I433M | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF181 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZNF471 | c.1127A>T p.N376I | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC141 | c.222C>T p.L74= | Silent (SNP) | VAF 10/257 reads (4%) | catalogued as COSV69464557; called by muse, mutect2
- CHI3L1 | c.240C>T p.L80= | Silent (SNP) | VAF 40/160 reads (25%) | catalogued as rs1558149434; called by muse, varscan2
- CPNE2 | c.657T>C p.D219= | Silent (SNP) | VAF 72/193 reads (37%) | called by muse, mutect2, varscan2
- CROCC | c.3216G>A p.T1072= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as rs774665432; called by muse, mutect2, varscan2
- MYCBP2 | c.2952A>G p.Q984= (on ENST00000357337; = p.Q1022= on NM_015057.5) | Silent (SNP) | VAF 90/257 reads (35%) | called by muse, mutect2, varscan2
- OR4C15 | c.447C>A p.G149= (on ENST00000314644; = p.G95= on NM_001001920.2) | Silent (SNP) | VAF 63/250 reads (25%) | called by muse, mutect2, varscan2
- PLCG1 | c.1089C>T p.C363= | Silent (SNP) | VAF 60/229 reads (26%) | catalogued as rs778460422; called by muse, mutect2, varscan2
- RASAL1 | c.756G>A p.V252= | Silent (SNP) | VAF 82/178 reads (46%) | called by muse, mutect2, varscan2
- REEP2 | c.411C>T p.A137= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs767756939; called by muse, mutect2, varscan2
- SALL3 | c.978G>A p.A326= | Silent (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2, varscan2
- SERPINC1 | c.1053C>T p.H351= | Silent (SNP) | VAF 66/510 reads (13%) | called by muse, mutect2, varscan2
- SLC16A1 | c.24A>G p.P8= | Silent (SNP) | VAF 94/253 reads (37%) | catalogued as rs11551865; called by muse, mutect2, varscan2
- SLC30A9 | c.564C>G p.A188= | Silent (SNP) | VAF 17/335 reads (5%) | called by muse, mutect2
- TENM2 | c.3249G>A p.L1083= (on ENST00000518659 / NM_001122679.2; = p.L851= on NM_001080428.3) | Silent (SNP) | VAF 97/307 reads (32%) | called by muse, mutect2, varscan2
- TMEM238 | c.264C>T p.L88= | Silent (SNP) | VAF 90/223 reads (40%) | called by muse, mutect2, varscan2
- AP000812.4 | c.*1515G>C | 3'UTR (SNP) | VAF 159/410 reads (39%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1382_*1383dup | 3'UTR (INS) | VAF 102/272 reads (38%) | called by mutect2, varscan2
- TNRC6A | c.-61G>T | 5'UTR (SNP) | VAF 80/226 reads (35%) | called by muse, varscan2
- TNRC6C | chr17:78004242 G>C | 5'Flank (SNP) | VAF 83/251 reads (33%) | called by muse, mutect2, varscan2
